Somatic mutation profile of tumor specimen TCGA-EK-A2RC-01A (aliquot TCGA-EK-A2RC-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 33.8 years (12,353 days).
Specimen TCGA-EK-A2RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6b5205b-a673-457d-b39a-bb6b09097c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RC-10A (Blood Derived Normal), aliquot TCGA-EK-A2RC-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43a8f70-b445-44d5-8129-25d081c054d3

The open-access MAF lists 193 somatic variants for this specimen: 135 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 54, Nonsense Mutation 10, RNA 2, Intron 2, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2
- CREBBP | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as rs1555475250, COSV52121775; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs769698072, COSV60198827; called by muse, mutect2, varscan2
- ABCA4 | c.5010G>C p.E1670D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV64673151; called by muse, mutect2, varscan2
- AC244197.3 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as CM162014, COSV61712175; called by muse, mutect2, varscan2
- ACAP2 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV58751598; called by muse, mutect2, varscan2
- ADAM18 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV55846709; called by muse, mutect2, varscan2
- AFF3 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57852449; called by muse, mutect2, varscan2
- AHI1 | c.2472G>C p.L824F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55626941; called by muse, mutect2, varscan2
- AKAP13 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV63455163; called by muse, mutect2, varscan2
- ALOXE3 | c.2046C>G p.I682M | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59075426; called by muse, mutect2, varscan2
- ALPK3 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV51932845; called by muse, mutect2, varscan2
- ALX1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1443144887, COSV57492108; called by muse, mutect2, varscan2
- AMBRA1 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV54053037; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3910C>T p.H1304Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51845942; called by muse, mutect2, varscan2
- ASAH2 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV61483223; called by muse, mutect2, varscan2
- BAAT | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52288728; called by muse, mutect2, varscan2
- BAP1 | c.1313C>G p.S438* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV56233716; called by muse, mutect2, varscan2
- CAPRIN1 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV100403728, COSV100403787, COSV58219592; called by muse, mutect2, varscan2
- CCNK | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV66274681; called by muse, mutect2, varscan2
- CEP76 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV50866341; called by muse, mutect2, varscan2
- CFAP44 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV55610921; called by muse, mutect2, varscan2
- CHD4 | c.1758G>C p.K586N (on ENST00000357008 / NM_001363606.2; = p.K599N on NM_001273.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV58900024; called by muse, mutect2, varscan2
- CHN1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV55033154; called by muse, mutect2, varscan2
- CNGB3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV60688867; called by muse, mutect2, varscan2
- CNTLN | c.4217G>C p.R1406T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV66097890; called by muse, mutect2, varscan2
- COL4A2 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV64627712; called by muse, mutect2, varscan2
- COL8A1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as rs867581568, COSV53733803; called by muse, mutect2, varscan2
- DCC | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100500286, COSV59099654; called by muse, mutect2, varscan2
- DDR2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369217; called by muse, mutect2, varscan2
- DDX60 | c.3739G>C p.E1247Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV67096531; called by muse, mutect2, varscan2
- DGKE | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1405183242, COSV52349653; called by muse, mutect2, varscan2
- DHX33 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs775512646, COSV56578803; called by muse, mutect2, varscan2
- DLGAP1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265206208, COSV59800524; called by muse, mutect2, varscan2
- DNAH7 | c.6115A>C p.M2039L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV56762410; called by muse, mutect2, varscan2
- DNM1 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV57851054, COSV57851420, COSV57852347; called by muse, mutect2, varscan2
- DOCK4 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as rs369989375, COSV70233035; called by muse, mutect2, varscan2
- EHMT2 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV100977162; called by muse, mutect2, varscan2
- EOLA2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV62207203; called by muse, mutect2, varscan2
- ERC1 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as COSV61694320; called by muse, mutect2, varscan2
- EXOC3L2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV52972841; called by muse, mutect2, varscan2
- FAM13A | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52001709; called by muse, mutect2, varscan2
- FAM47C | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.364); catalogued as rs376992053, COSV63726202; called by muse, mutect2, varscan2
- FBXW10 | c.234G>C p.Q78H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57316630; called by muse, mutect2, varscan2
- FES | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.482); catalogued as rs575070040, COSV60997999, COSV61000839; called by muse, mutect2
- FMNL1 | c.768G>C p.E256D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100056601, COSV58956708; called by muse, mutect2, varscan2
- FMNL1 | c.839G>C p.C280S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58956716; called by muse, mutect2, varscan2
- FMNL1 | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58956460; called by muse, mutect2, varscan2
- FNBP1 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63086868; called by muse, mutect2, varscan2
- FOS | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.62); catalogued as COSV57839500; called by muse, mutect2, varscan2
- GALNS | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs1199639828, CM1211650, COSV51936227; called by muse, mutect2, varscan2
- GFM2 | c.2334G>C p.L778F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV54667605; called by muse, mutect2, varscan2
- GNAI1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63522679; called by muse, mutect2, varscan2
- GPR39 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV61416378; called by muse, mutect2, varscan2
- GRM8 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as COSV58822165; called by muse, mutect2, varscan2
- HPS4 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61103295; called by muse, mutect2, varscan2
- HSPA8 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.247); catalogued as COSV57083767; called by muse, mutect2, varscan2
- HTR1A | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755504345, COSV60500604; called by muse, mutect2, varscan2
- HTR3E | c.885G>A p.M295I (on ENST00000415389 / NM_001256613.1; = p.M310I on NM_182589.2) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as COSV58946623; called by muse, mutect2, varscan2
- KCNK4 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60453933; called by muse, mutect2, varscan2
- KMT2C | c.3652C>T p.Q1218* | Nonsense Mutation (SNP) | VAF 45/173 reads (26%) | catalogued as COSV51274756, COSV51478855; called by muse, mutect2, varscan2
- KRT32 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56786531; called by muse, mutect2, varscan2
- LGI4 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.056); catalogued as COSV59533414; called by muse, mutect2, varscan2
- LIPH | c.841T>C p.C281R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56183790; called by muse, mutect2, varscan2
- LRP2 | c.12319G>A p.G4107R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV99787503; called by muse, mutect2, varscan2
- LRRIQ1 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV67812951; called by muse, mutect2, varscan2
- LVRN | c.1976G>C p.R659T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63497114; called by muse, mutect2, varscan2
- MAP3K10 | c.2543G>A p.G848D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV53421943; called by muse, mutect2, varscan2
- MB21D2 | c.747G>C p.Q249H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV66663148; called by muse, mutect2, varscan2
- MECOM | c.1870G>C p.D624H (on ENST00000468789 / NM_001105078.4; = p.D812H on NM_004991.4) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as COSV52963666; called by muse, mutect2, varscan2
- MED12 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV61338521; called by muse, mutect2, varscan2
- MEMO1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.354); catalogued as rs764901697, COSV54451683; called by muse, mutect2, varscan2
- METTL18 | c.921G>C p.Q307H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV53678330, COSV99609444; called by muse, mutect2, varscan2
- MIB2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1393771131, COSV61755666; called by muse, mutect2, varscan2
- MICAL2 | c.5468C>T p.S1823F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV56285739; called by muse, mutect2, varscan2
- MIEF1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57478773; called by muse, mutect2, varscan2
- MXRA5 | c.2931C>G p.Y977* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV54233237; called by muse, mutect2, varscan2
- NAT1 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV56985065; called by muse, mutect2, varscan2
- NCL | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs773553375, COSV59545674; called by muse, mutect2, varscan2
- NEB | c.13593G>A p.L4531= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as rs1378049269, COSV51190916; called by muse, mutect2, varscan2
- NSD1 | c.5036C>A p.S1679* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV61773224, COSV61775522; called by muse, mutect2, varscan2
- OR13D1 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV59513829; called by muse, mutect2, varscan2
- OR2D3 | c.763T>G p.S255A | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV53492822; called by muse, mutect2, varscan2
- PACS1 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV57697460; called by muse, mutect2
- PDE12 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV60818324; called by muse, mutect2, varscan2
- PFAS | c.1826G>T p.R609I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100118867; called by muse, mutect2, varscan2
- PLA2R1 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51777963; called by muse, mutect2, varscan2
- PPP4R3A | c.1864G>C p.E622Q (on ENST00000554943 / NM_001366432.1; = p.E609Q on NM_001284280.1) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV61504386; called by muse, mutect2, varscan2
- PRKAA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64803501, COSV64805114; called by muse, mutect2, varscan2
- PRKCI | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV55518547, COSV55520388; called by muse, mutect2, varscan2
- PSMB2 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV64698689; called by muse, mutect2, varscan2
- PTPN4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs1420191465, COSV55300934; called by muse, mutect2, varscan2
- PZP | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.035); catalogued as COSV54359271; called by muse, mutect2
- RFLNA | c.404G>T p.S135I (on ENST00000546355 / NM_001365156.1; = p.S54I on NM_181709.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58038040; called by muse, mutect2
- RFX7 | c.242G>A p.G81E (on ENST00000559447 / NM_001368074.1; = p.G178E on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57962776; called by muse, mutect2
- RITA1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs767217662, COSV58373235; called by muse, mutect2, varscan2
- RTL5 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65453240; called by muse, mutect2, varscan2
- RTN1 | c.1780T>A p.Y594N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50722725; called by muse, mutect2, varscan2
- SCAMP3 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56944891; called by muse, mutect2, varscan2
- SCRIB | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV57585979, COSV57593321; called by muse, mutect2, varscan2
- SDK1 | c.4870G>A p.E1624K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as COSV67366580; called by muse, mutect2, varscan2
- SEZ6L | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV50662713; called by muse, mutect2, varscan2
- SF1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111668; called by muse, mutect2, varscan2
- SH3TC1 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV55283787; called by muse, mutect2, varscan2
- SIDT2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV54056647; called by muse, mutect2, varscan2
- SLC24A1 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372351507; called by muse, mutect2
- SLC25A47 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59925307; called by muse, mutect2, varscan2
- SLC6A6 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV62649207; called by muse, mutect2, varscan2
- SLC9B1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.836); catalogued as COSV56469662; called by muse, mutect2, varscan2
- SNX9 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67583888, COSV67584035; called by muse, mutect2, varscan2
- SRPX2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV65933511; called by muse, mutect2, varscan2
- SSBP4 | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV54210199; called by muse, mutect2
- STXBP4 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54841224; called by muse, mutect2, varscan2
- TAF1L | c.4158G>C p.L1386F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54261314; called by muse, mutect2, varscan2
- TAS2R41 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV68765198; called by muse, mutect2, varscan2
- TBC1D2B | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56041233; called by muse, mutect2, varscan2
- TBL1XR1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV61790370; called by muse, mutect2, varscan2
- TBXT | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51616506; called by muse, mutect2, varscan2
- THSD7B | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55681102; called by muse, mutect2, varscan2
- TIE1 | c.3057G>C p.W1019C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65249527; called by muse, mutect2, varscan2
- TMC2 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV62651974, COSV62652273; called by muse, mutect2, varscan2
- TMCO4 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs534456252, COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2, varscan2
- TOPORS | c.2476C>T p.Q826* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV62116795; called by muse, mutect2, varscan2
- TRPC5 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.861); catalogued as COSV53289308; called by muse, mutect2, varscan2
- TRPM1 | c.1761G>C p.K587N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs1237668584, COSV56633909; called by muse, mutect2, varscan2
- TTF2 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV65632488; called by muse, mutect2, varscan2
- TTN | c.35313G>T p.K11771N (on ENST00000591111; = p.K10844N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | PolyPhen possibly damaging (0.714); catalogued as COSV60195358, COSV60341103; called by muse, mutect2, varscan2
- TUT1 | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1189094093, COSV53469839; called by muse, mutect2, varscan2
- ZBTB1 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs143630259, COSV62439581; called by muse, mutect2, varscan2
- ZCCHC13 | c.500G>T p.*167Lext*15 | Nonstop Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV59866225; called by muse, mutect2, varscan2
- ZNF432 | c.1267C>G p.H423D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55416175, COSV55416269; called by muse, mutect2, varscan2
- ZNF630 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV52096193; called by muse, mutect2, varscan2
- ZNF74 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs568434993, COSV62620759; called by muse, mutect2, varscan2
- CCNL2 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- RBM5 | c.662_663del p.E221Vfs*10 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by pindel, varscan2
- ABCA4 | c.4767G>C p.V1589= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1370704703, COSV64673155; called by muse, varscan2
- ADCY6 | c.3333G>A p.V1111= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV57167630; called by muse, mutect2, varscan2
- ADD1 | c.1299C>G p.L433= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99296277; called by muse, mutect2, varscan2
- ARAP3 | c.4629C>G p.L1543= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV53350422; called by muse, mutect2, varscan2
- CDK5R1 | c.189G>A p.K63= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV55579329; called by muse, mutect2, varscan2
- CFAP65 | c.4011C>T p.T1337= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs762555202, COSV58560442; called by muse, mutect2, varscan2
- CNTNAP1 | c.2550C>T p.F850= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs756084575, COSV52850086; called by muse, mutect2, varscan2
- CX3CL1 | c.456G>A p.G152= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV50055775; called by muse, mutect2, varscan2
- DMBT1 | c.7452C>T p.S2484= (on ENST00000338354 / NM_001377530.1; = p.S1727= on NM_004406.3) | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs753917841, COSV57542211; called by muse, mutect2, varscan2
- DNM2 | c.2208C>T p.I736= (on ENST00000355667 / NM_001005360.3; = p.I732= on NM_004945.3) | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs755163979, COSV99283979; called by muse, mutect2, varscan2
- EP400 | c.3906C>T p.D1302= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs368953719; called by muse, mutect2, varscan2
- EPHA5 | c.2689C>T p.L897= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV56639217, COSV56642675, COSV56661951; called by muse, mutect2, varscan2
- EPHB6 | c.2130C>T p.A710= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs117493419; called by muse, mutect2, varscan2
- ESYT3 | c.1767G>C p.L589= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV67440782; called by muse, mutect2, varscan2
- EVC2 | c.2292C>G p.L764= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs200598574, COSV100185574; called by muse, mutect2, varscan2
- FBXL16 | c.789C>T p.I263= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1175094994, COSV60964414; called by muse, mutect2, varscan2
- GPR4 | c.588C>G p.L196= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs1432893280, COSV59916841; called by muse, mutect2, varscan2
- IL1RAPL1 | c.153C>T p.I51= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV56257439; called by muse, mutect2, varscan2
- INHBB | c.456C>T p.L152= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs145813735; called by muse, mutect2, varscan2
- INSRR | c.1146C>G p.L382= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV63872671; called by muse, mutect2, varscan2
- IQSEC2 | c.2613C>T p.L871= (on ENST00000642864 / NM_001111125.3; = p.L666= on NM_015075.2) | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1342422354, COSV64724453; called by muse, mutect2, varscan2
- KIF26A | c.2424C>T p.N808= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs367843200; called by muse, mutect2, varscan2
- KRT3 | c.1371C>T p.L457= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs376658995; called by muse, mutect2, varscan2
- MGA | c.7368C>G p.S2456= (on ENST00000219905 / NM_001164273.1; = p.S2247= on NM_001080541.2) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs748686738, COSV99579335; called by muse, mutect2, varscan2
- MGRN1 | c.1299C>T p.I433= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs747705148, COSV52150539; called by muse, mutect2, varscan2
- MYH1 | c.3072G>A p.L1024= | Silent (SNP) | VAF 63/202 reads (31%) | catalogued as COSV56847350; called by muse, mutect2, varscan2
- NPBWR1 | c.345C>T p.I115= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV58696069; called by muse, mutect2, varscan2
- PARD6G | c.438C>T p.I146= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV62061095; called by muse, mutect2, varscan2
- PKD1 | c.5556C>T p.V1852= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV51915097; called by muse, mutect2, varscan2
- PKDREJ | c.4870C>T p.L1624= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs893268639, COSV53548938; called by muse, varscan2
- PKDREJ | c.4854C>T p.F1618= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1278788053, COSV53546131; called by muse, varscan2
- PLAU | c.777C>T p.L259= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs1466671540, COSV65641239; called by muse, mutect2, varscan2
- PNMA1 | c.183G>A p.A61= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54094531; called by muse, mutect2, varscan2
- POLR2A | c.1119C>G p.L373= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV59491820; called by muse, mutect2, varscan2
- PPL | c.84G>A p.S28= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs754578337, COSV62046675; called by muse, mutect2, varscan2
- PRAMEF8 | c.1050G>A p.L350= | Silent (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- PTGFRN | c.2025C>T p.L675= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV67798123; called by muse, mutect2, varscan2
- RAB5IF | c.252C>G p.L84= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV53411043; called by muse, mutect2, varscan2
- SALL2 | c.357G>A p.E119= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1226341883, COSV100444259; called by muse, mutect2
- SCRIB | c.1692C>T p.Y564= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs771432032, COSV57585960; called by muse, mutect2, varscan2
- SHISAL1 | c.174C>G p.L58= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV66987881; called by muse, mutect2, varscan2
- SLC12A3 | c.2172C>T p.L724= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs201038360; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAT2 | c.591G>A p.K197= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV58475214; called by muse, mutect2, varscan2
- STAT2 | c.498G>A p.L166= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV58475224; called by muse, mutect2, varscan2
- TAF1B | c.1107C>G p.L369= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV55155795; called by muse, mutect2, varscan2
- TMEM132D | c.960C>T p.F320= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV70602732; called by muse, mutect2, varscan2
- TUT1 | c.2442G>T p.L814= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53469829; called by muse, mutect2, varscan2
- UBA6 | c.2265C>G p.L755= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100451638; called by mutect2, varscan2
- UBR4 | c.2502C>T p.V834= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV64388418; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3702G>A p.L1234= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV51954968; called by muse, mutect2, varscan2
- UQCR11 | c.6G>A p.V2= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53647943; called by muse, mutect2
- VARS1 | c.2670G>A p.L890= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100791795; called by muse, mutect2, varscan2
- ZNF432 | c.912C>G p.L304= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV55416279, COSV55417689; called by muse, mutect2, varscan2
- ZNF618 | c.1452G>C p.L484= (on ENST00000374126 / NM_001318042.2; = p.L391= on NM_133374.2) | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99929754; called by muse, mutect2, varscan2
- LINC01098 | n.752C>G | RNA (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- NUDCD3 | c.509+16669C>G | Intron (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+1834G>C | Intron (SNP) | VAF 21/65 reads (32%) | catalogued as rs199942335; called by muse, mutect2, varscan2
- RPL23AP42 | n.46G>A | RNA (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
